Somatic mutation profile of tumor specimen CPT008926 (aliquot CPT008926-0002) from CPTAC case 03BR011, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Primary diagnosis: Invasive lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.0 years (25,945 days).
Specimen CPT008926: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1056634e-2ddc-497a-9c1c-d90a96ca2511.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008548 (Blood Derived Normal), aliquot CPT008548-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53903b1d-5635-4215-abd0-8fc8e949a62f

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Nonsense Mutation 4, Intron 3, 3'UTR 2, Splice Region 1, In Frame Del 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 89/237 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APBA1 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as rs374824691; called by muse, mutect2, varscan2
- ARHGAP45 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV57435970; called by muse, mutect2, varscan2
- CHRNG | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 132/538 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs759015914; called by muse, mutect2, varscan2
- CNGA2 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs141325552; called by muse, mutect2, varscan2
- DLGAP1 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 90/153 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770425612; called by muse, mutect2, varscan2
- FAM216B | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs769993048; called by muse, mutect2, varscan2
- HECW1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 162/419 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs770727253, COSV67836527; called by muse, mutect2, varscan2
- KCNT1 | c.1273C>T p.R425* (on ENST00000488444; = p.R444* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs764562570, COSV53694931; called by muse, mutect2, varscan2
- KIF6 | c.2267G>A p.C756Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750933157; called by muse, mutect2
- KLHL4 | c.951C>A p.N317K | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100909549; called by muse, mutect2, varscan2
- MACF1 | c.16698G>T p.K5566N (on ENST00000372915; = p.K3608N on NM_012090.5) | Missense Mutation (SNP) | VAF 59/271 reads (22%) | catalogued as rs1210656305; called by muse, mutect2, varscan2
- MAGEB6 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 42/350 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV66871893, COSV66872236; called by muse, mutect2, varscan2
- MED12 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV61352563; called by muse, mutect2, varscan2
- OR8B3 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV63542316; called by mutect2, varscan2
- PROSER2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.5); catalogued as rs747565780; called by mutect2, varscan2
- SYNE1 | c.19561G>A p.E6521K (on ENST00000367255 / NM_182961.4; = p.E6450K on NM_033071.3) | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99559664; called by muse, mutect2, varscan2
- TAF3 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs376569744; called by muse, mutect2, varscan2
- TAP2 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 56/166 reads (34%) | catalogued as rs1379914598, COSV66498153; called by muse, mutect2
- WDR97 | c.757G>C p.A253P | Missense Mutation (SNP) | VAF 87/478 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs980046754; called by muse, mutect2, varscan2
- ZNF580 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs560117278; called by muse, mutect2, varscan2
- ABHD18 | c.487A>G p.N163D (on ENST00000398965 / NM_001039717.2; = p.N36D on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADCYAP1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGAP3 | c.1143dup p.E382Rfs*7 | Frame Shift Ins (INS) | VAF 20/203 reads (10%) | called by mutect2, pindel
- ARL13B | c.962A>G p.K321R (on ENST00000394222 / NM_001174150.2; = p.K214R on NM_144996.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC158 | c.1783_1794del p.L595_E598del | In Frame Del (DEL) | VAF 54/153 reads (35%) | called by mutect2, pindel, varscan2
- CDH1 | c.388-20_406del p.X130_splice | Splice Site (DEL) | VAF 68/155 reads (44%) | called by mutect2, pindel, varscan2
- CHST13 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- DEFB129 | c.55A>C p.T19P | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GABPB1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MKRN3 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 79/425 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSF | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR10C1 | c.466G>A p.V156M (on ENST00000622521; = p.V154M on NM_013941.3) | Missense Mutation (SNP) | VAF 110/573 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OR4D10 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB7 | c.1373T>A p.L458Q | Missense Mutation (SNP) | VAF 98/507 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDPN | c.28G>A p.V10I (on ENST00000621990; = p.V86I on NM_006474.4) | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PFKM | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 77/428 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG5 | c.-53-7C>T | Splice Region (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- SLC7A6OS | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLIT2 | c.4000G>T p.E1334* | Nonsense Mutation (SNP) | VAF 56/206 reads (27%) | called by mutect2, varscan2
- STAMBP | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- STX11 | c.844T>G p.C282G | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TMEM101 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRO | c.2627G>A p.S876N | Missense Mutation (SNP) | VAF 192/558 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YWHAH | c.401del p.L134* | Frame Shift Del (DEL) | VAF 104/682 reads (15%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.240C>T p.N80= | Silent (SNP) | VAF 65/310 reads (21%) | catalogued as rs763870886; called by muse, mutect2, varscan2
- CYP19A1 | c.705T>C p.F235= | Silent (SNP) | VAF 34/138 reads (25%) | called by muse, mutect2
- DUOXA2 | c.432C>T p.N144= | Silent (SNP) | VAF 28/604 reads (5%) | catalogued as COSV50994624, COSV99973272; called by muse, mutect2
- FOXQ1 | c.612C>T p.F204= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- HPCA | c.339C>T p.N113= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs575651333; called by muse, mutect2, varscan2
- IGKV1-39 | c.30G>A p.L10= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2, varscan2
- IRX6 | c.717C>A p.T239= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- NECTIN4 | c.555G>A p.T185= | Silent (SNP) | VAF 77/734 reads (10%) | catalogued as COSV100919788, COSV63513667; called by muse, mutect2, varscan2
- OR9Q1 | c.81C>A p.L27= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV100110508; called by muse, mutect2, varscan2
- PHF8 | c.1878C>A p.T626= (on ENST00000357988 / NM_001184896.1; = p.T590= on NM_015107.3) | Silent (SNP) | VAF 47/334 reads (14%) | called by muse, mutect2, varscan2
- SGO1 | c.1407A>G p.P469= (on ENST00000263753 / NM_001012410.5; = p.P200= on NM_138484.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV55424508; called by muse, varscan2
- ZGRF1 | c.138G>A p.E46= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100005328; called by muse, mutect2, varscan2
- ZNF423 | c.3360C>T p.P1120= (on ENST00000563137 / NM_001379286.1; = p.P1112= on NM_015069.4) | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs372366526; called by muse, mutect2, varscan2
- CCKBR | c.-19G>A | 5'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- EDC3 | c.1192+12G>A | Intron (SNP) | VAF 325/818 reads (40%) | called by muse, mutect2, varscan2
- GABRA6 | c.530-22T>A | Intron (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- KLRD1 | c.*538G>T | 3'UTR (SNP) | VAF 10/72 reads (14%) | catalogued as rs573269294; called by muse, mutect2, varscan2
- PRRT1 | c.*450C>T | 3'UTR (SNP) | VAF 52/137 reads (38%) | catalogued as rs1218707355, COSV52999186; called by muse, mutect2, varscan2
- PTPN22 | c.88-4742C>A | Intron (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
